Somatic mutation profile of tumor specimen TARGET-10-PAREAL-09A (aliquot TARGET-10-PAREAL-09A-01D) from TARGET case TARGET-10-PAREAL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.3 years (3,385 days).
Specimen TARGET-10-PAREAL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc7b4aa8-ff2e-4d35-9e48-b03ef318526b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREAL-10A (Blood Derived Normal), aliquot TARGET-10-PAREAL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6aa5256f-e999-497f-bba6-9c0845a499da

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK2 | c.5373del p.I1792Sfs*13 | Frame Shift Del (DEL) | VAF 29/80 reads (36%) | catalogued as rs1297941440, COSV64496748; called by mutect2, pindel, varscan2
- DNAH17 | c.10309C>T p.R3437W | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763820523, COSV67753709; called by muse, mutect2, varscan2
- MAGEB16 | c.844A>G p.K282E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs1421543233; called by muse, mutect2
- MMP3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs782643785, COSV55406397; called by muse, mutect2, varscan2
- NFAT5 | c.4141A>G p.M1381V | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs1368863779; called by muse, mutect2, varscan2
- OR52I2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs747433430, COSV57044821; called by muse, mutect2, varscan2
- PAPLN | c.901C>A p.R301S (on ENST00000554301; = p.R274S on NM_173462.4) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV53722986; called by muse, mutect2, varscan2
- RUBCNL | c.986+1G>A p.X329_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as rs201786371; called by muse, varscan2
- EFCAB5 | c.2251dup p.I751Nfs*9 | Frame Shift Ins (INS) | VAF 9/95 reads (9%) | called by mutect2, pindel
- GNB5 | c.886T>C p.F296L (on ENST00000261837 / NM_016194.4; = p.F254L on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ARMCX4 | c.1038+1084G>A | Intron (SNP) | VAF 11/106 reads (10%) | catalogued as rs1051378955; called by muse, mutect2, varscan2
